Somatic mutation profile of tumor specimen TCGA-EM-A3AP-01A (aliquot TCGA-EM-A3AP-01A-12D-A20C-08) from TCGA case TCGA-EM-A3AP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 31.7 years (11,592 days).
Specimen TCGA-EM-A3AP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6113f1bd-c93a-48b9-a716-c1b29d5d1e25.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3AP-10A (Blood Derived Normal), aliquot TCGA-EM-A3AP-10A-01D-A20C-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/211fecd8-c55f-42be-89df-70e5c687f819

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 102/340 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- CPE | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV68582230; called by muse, mutect2
- CYB5R2 | c.657T>G p.I219M | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs996280137, COSV55087172; called by muse, mutect2, varscan2
- DGCR8 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100707762, COSV61225642; called by muse, mutect2, varscan2
- IK | c.338A>T p.D113V | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70258162; called by muse, mutect2, varscan2
- KIF14 | c.3581T>A p.M1194K | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV66263669; called by muse, mutect2, varscan2
- PDPR | c.2063A>T p.H688L | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV55355792; called by muse, mutect2, varscan2
- TRDV3 | c.54T>C p.C18= | Silent (SNP) | VAF 25/46 reads (54%) | called by muse, mutect2, varscan2
